Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3UB, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3UB-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

CC:

Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Bleeding secondary to jejunal mass.

Specimens Submitted:
1: SP: Proximal jejunum

DIAGNOSIS:

1. SMALL BOWEL, PROXIMAL JEJUNUM: RESECTION:
- SMOOTH MUSCLE NEOPLASM, CONSISTENT WITH A LOW GRADE LEIOMYOSARCOMA, OF JEJUNUM, SEE NOTE.
- THE TUMOR INVOLVES TRANSMURAL SMALL BOWEL WALL WITH EXTENSION TO THE MUCOSAL SURFACE WITH EROSION AND IS PRESENT <1 MM FOR THE SEROSAL SURFACE.
- THE TUMOR MEASURES 2.7 CM IN GREATEST DIMENSION.
- THE TUMOR EXHIBITS A NODULAR AND INFILTRATING GROWTH PATTERN.
- NO TUMOR NECROSIS IS NOTED.
- THE ESTIMATED MITOTIC ACTIVITY IS 2-3/10 HPF.
- NO VASCULAR INVASION IS IDENTIFIED.
- SURGICAL MARGINS OF RESECTION ARE FREE OF TUMOR.
- THE UNINVOLVED SMALL BOWEL MUCOSA IS UNREMARKABLE.

NOTE: IMMUNOSTAINS REVEAL THAT THE TUMOR CELLS ARE POSITIVE FOR DESMIN AND SMA; THEY ARE NEGATIVE FOR S100, CD34, AND CD117. THE ESTIMATED PROLIFERATIVE INDEX (MIB-1) IS UP TO 10%.
THIS CASE HAS BEEN REVIEWED WITH [REDACTED] IN CONSULTATION.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1.) The specimen is received fresh labeled "proximal jejunum" and consists of an unoriented portion of small bowel measuring 9.0 cm in length and 7.6

** Continued on next page **

ICD-O-3

leiomyosarcoma, NOS
8890/3

Site:

path: jejunum C17.1

CQCF: Retroperitoneum C48.0

5-2-12
ED

[page 2 of 2]
----- Page 2 of 2
cm in circumference. There is a tan-white firm fungating tumor measuring 2.7 x 2.2 x 1.8 cm located 3.7 cm from one resection and 2.5 cm from the other resection end. The tumor penetrates the bowel wall and is present on the serosal surface. This area is inked black. TPS is taken. Gross photographs are taken. The entire tumor is submitted. The remaining specimen is representatively submitted.

Summary of sections:
M1 - one shaved margin
M2 opposite shaved margin
T tumor
D - normal duodenum

Summary of Sections:
Part 1: SP: Proximal jejunum

Block	Sect.	Site	PCs
1		D	1
1		M1	1
1		M2	1
5		T	5

** End of Report **

Source: NCI Genomic Data Commons file 3fb6e051-9e80-4e3a-8b10-77583196b193 (TCGA-DX-A3UB.D8B3F485-3154-457E-ACC2-0DCAC3AA4433.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).